CCDI case PBCRYI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/3189dddf-1d21-4aa7-b659-0ec5bbf12ce2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor with rhabdomyoblastic differentiation: ICD-O-3 morphology code: 9561/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.3 years (6,320 days).

Biospecimens (3 samples)
- Sample 0DY8K9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DY8KF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DY8KP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
